Somatic mutation profile of tumor specimen TCGA-12-0692-01A (aliquot TCGA-12-0692-01A-01D-1492-08) from TCGA case TCGA-12-0692, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 75.3 years (27,519 days).
Specimen TCGA-12-0692-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 727bb55b-9f33-443c-94d7-f11494ff6f76.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-12-0692-10A (Blood Derived Normal), aliquot TCGA-12-0692-10A-01D-1492-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f2c2e294-b401-44dc-8e4a-cb5294320a02

The open-access MAF lists 68 somatic variants for this specimen: 52 protein-altering or splice-affecting, 14 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 43, Silent 14, Splice Site 3, Frame Shift Del 3, Nonsense Mutation 2, Intron 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC9 | c.4151C>A p.T1384K | Missense Mutation (SNP) | VAF 54/123 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV53971376; called by muse, mutect2, varscan2
- ADAM29 | c.1537G>A p.A513T | Missense Mutation (SNP) | VAF 67/154 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs760244397, COSV63663582; called by muse, mutect2, varscan2
- AFM | c.1189G>A p.A397T | Missense Mutation (SNP) | VAF 42/107 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.174); catalogued as rs372542885; called by muse, mutect2
- ANO2 | c.1003C>T p.R335C (on ENST00000356134 / NM_001278597.3; = p.R339C on NM_001278596.3) | Missense Mutation (SNP) | VAF 31/50 reads (62%) | SIFT tolerated (0.06); PolyPhen benign (0.201); catalogued as rs372991029, COSV59050232; called by muse, mutect2, varscan2
- ATP10B | c.1340G>A p.R447H | Missense Mutation (SNP) | VAF 132/274 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs376023056; called by muse, mutect2, varscan2
- BARD1 | c.1837del p.A613Qfs*6 | Frame Shift Del (DEL) | VAF 28/62 reads (45%) | catalogued as COSV53613149; called by mutect2, pindel, varscan2
- CAMSAP1 | c.1859C>T p.P620L | Missense Mutation (SNP) | VAF 63/136 reads (46%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs756052830, COSV56722598; called by muse, mutect2, varscan2
- CCAR1 | c.246+1G>C p.X82_splice | Splice Site (SNP) | VAF 22/30 reads (73%) | catalogued as COSV56269821; called by muse, mutect2
- CD109 | c.1121G>A p.R374H | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.022); catalogued as rs1213149278, COSV54649392; called by muse, mutect2, varscan2
- CENPS-CORT | c.133C>T p.Q45* | Nonsense Mutation (SNP) | VAF 98/246 reads (40%) | catalogued as COSV58364033; called by muse, varscan2
- CRTAC1 | c.905G>A p.R302H | Missense Mutation (SNP) | VAF 81/103 reads (79%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.86); catalogued as rs149424033; called by muse, mutect2, varscan2
- CYP2D6 | c.725G>A p.R242H | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.023); catalogued as rs779730092, COSV62243013; called by muse, mutect2, varscan2
- DEFB114 | c.104G>A p.R35H | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0); catalogued as rs146020038, COSV59037894; called by muse, mutect2, varscan2
- DNAH3 | c.10360T>A p.W3454R | Missense Mutation (SNP) | VAF 19/121 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV54521452; called by muse, mutect2, varscan2
- DPP10 | c.1951-2A>G p.X651_splice | Splice Site (SNP) | VAF 9/19 reads (47%) | catalogued as COSV59686185; called by muse, mutect2, varscan2
- EDDM3B | c.115T>G p.L39V | Missense Mutation (SNP) | VAF 71/149 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.589); catalogued as rs201861023, COSV58746982; called by muse, mutect2, varscan2
- ENTHD1 | c.205C>T p.R69C | Missense Mutation (SNP) | VAF 108/259 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1463294299, COSV57318141, COSV57320234, COSV57323027; called by muse, mutect2, varscan2
- FLNA | c.3679G>A p.G1227R | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61042937; called by muse, mutect2
- FLT3 | c.2316A>T p.K772N | Missense Mutation (SNP) | VAF 51/107 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.248); catalogued as COSV54053920; called by muse, mutect2, varscan2
- GON4L | c.848A>C p.Q283P | Missense Mutation (SNP) | VAF 138/296 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV55193408; called by muse, mutect2, varscan2
- H3-4 | c.157C>T p.R53C | Missense Mutation (SNP) | VAF 60/141 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.8); catalogued as COSV64210419; called by muse, mutect2, varscan2
- IGF2BP1 | c.499C>T p.R167C | Missense Mutation (SNP) | VAF 48/111 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.676); catalogued as rs1364176184, COSV51731262; called by muse, mutect2, varscan2
- ITGAD | c.2669G>T p.R890M | Missense Mutation (SNP) | VAF 47/144 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV66757977; called by muse, mutect2, varscan2
- ITGAE | c.2098G>A p.V700I | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as rs967609574, COSV53993808; called by muse, mutect2, varscan2
- LGALS9B | c.47C>G p.P16R | Missense Mutation (SNP) | VAF 56/151 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60864951; called by muse, mutect2, varscan2
- LONRF3 | c.154C>T p.R52W | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.425); catalogued as COSV59152198; called by muse, mutect2
- MSL2 | c.1632T>A p.S544R | Missense Mutation (SNP) | VAF 63/173 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.29); catalogued as COSV53863808; called by muse, mutect2, varscan2
- NUP42 | c.695G>A p.G232D | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as COSV51729552; called by muse, mutect2
- OR1I1 | c.391C>T p.R131C | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as rs372952340; called by muse, mutect2, varscan2
- OR51F1 | c.460G>T p.G154C | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs1286300919, COSV58579728, COSV58580090; called by muse, mutect2, varscan2
- PCDHGB4 | c.1862C>T p.T621M | Missense Mutation (SNP) | VAF 37/99 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53920743; called by muse, mutect2, varscan2
- PCF11 | c.2792A>T p.D931V | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV53531118; called by muse, mutect2, varscan2
- PLXNB3 | c.793C>T p.R265C | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62797319; called by muse, mutect2, varscan2
- PPP6R3 | c.552+2T>G p.X184_splice | Splice Site (SNP) | VAF 110/243 reads (45%) | catalogued as COSV55726535; called by muse, mutect2, varscan2
- PRKAR1B | c.809C>T p.A270V | Missense Mutation (SNP) | VAF 14/226 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.312); catalogued as rs1317364396, COSV64318617; called by muse, mutect2
- SATL1 | c.815C>T p.P272L (on ENST00000395409; = p.P459L on NM_001012980.2) | Missense Mutation (SNP) | VAF 92/212 reads (43%) | SIFT tolerated (0.69); PolyPhen probably damaging (0.991); catalogued as COSV100260952, COSV60576680; called by muse, mutect2, varscan2
- STAG2 | c.446del p.T149Mfs*34 | Frame Shift Del (DEL) | VAF 28/76 reads (37%) | catalogued as COSV54362445; called by mutect2, pindel*, varscan2
- STK31 | c.2182C>T p.R728* | Nonsense Mutation (SNP) | VAF 83/329 reads (25%) | catalogued as rs767028140, COSV63453851; called by muse, mutect2, varscan2
- STK35 | c.1480C>T p.R494C | Missense Mutation (SNP) | VAF 58/170 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as rs746321390, COSV55690545; called by muse, mutect2, varscan2
- TAF1 | c.1736G>A p.R579Q (on ENST00000373790 / NM_138923.4; = p.R600Q on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.027); catalogued as COSV99334068; called by muse, mutect2, varscan2
- TBL1X | c.544G>A p.V182I | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs200562052, COSV54280026; called by muse, mutect2, varscan2
- TEK | c.3007C>T p.R1003C | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772600804, COSV66228950; called by muse, mutect2, varscan2
- TMEM255B | c.751G>A p.A251T | Missense Mutation (SNP) | VAF 43/109 reads (39%) | SIFT tolerated (0.7); PolyPhen benign (0.018); catalogued as rs368613950; called by muse, mutect2, varscan2
- TNFSF14 | c.103G>T p.V35L | Missense Mutation (SNP) | VAF 11/259 reads (4%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as COSV55590580; called by muse, mutect2
- UNC5D | c.310G>C p.D104H | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV54794183; called by muse, mutect2
- WNT2 | c.205G>A p.V69M | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.066); catalogued as rs371599061, COSV99038559; called by muse, mutect2, varscan2
- XIRP1 | c.5006C>A p.S1669Y | Missense Mutation (SNP) | VAF 63/146 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61138480; called by muse, mutect2, varscan2
- ZBTB33 | c.1048G>A p.V350I | Missense Mutation (SNP) | VAF 78/192 reads (41%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.969); catalogued as rs1231502325, COSV58533933; called by muse, mutect2, varscan2
- ZDBF2 | c.457C>T p.H153Y | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.46); PolyPhen benign (0.006); catalogued as COSV65625925; called by muse, mutect2, varscan2
- ZNF560 | c.613G>A p.A205T | Missense Mutation (SNP) | VAF 43/82 reads (52%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV56867859; called by muse, mutect2, varscan2
- CNTN5 | c.2917+1_2917+2dup | Frame Shift Ins (INS) | VAF 12/36 reads (33%) | called by mutect2, varscan2
- TRMT6 | c.332_333del p.I111Kfs*9 | Frame Shift Del (DEL) | VAF 59/227 reads (26%) | called by mutect2, pindel, varscan2
- FAM181A | c.492C>T p.N164= | Silent (SNP) | VAF 5/51 reads (10%) | catalogued as COSV50888556; called by muse, mutect2
- NLRP4 | c.2673G>A p.T891= | Silent (SNP) | VAF 66/175 reads (38%) | catalogued as rs201059514; called by muse, mutect2, varscan2
- OLFML2B | c.141C>T p.N47= | Silent (SNP) | VAF 31/153 reads (20%) | catalogued as rs770352048, COSV54196407; called by muse, mutect2, varscan2
- PIWIL1 | c.2112A>G p.V704= | Silent (SNP) | VAF 69/125 reads (55%) | catalogued as COSV55346765; called by muse, mutect2, varscan2
- PLA2G15 | c.372G>A p.L124= | Silent (SNP) | VAF 32/88 reads (36%) | catalogued as COSV54723162; called by muse, mutect2, varscan2
- PLXNA3 | c.2844C>T p.S948= | Silent (SNP) | VAF 129/320 reads (40%) | catalogued as rs199634043, COSV63754085; called by muse, mutect2, varscan2
- POLA1 | c.2247C>T p.A749= | Silent (SNP) | VAF 59/150 reads (39%) | catalogued as COSV66886264; called by muse, mutect2, varscan2
- RBM45 | c.1284T>C p.N428= (on ENST00000616198 / NM_001365579.1; = p.N426= on NM_152945.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 11/111 reads (10%) | catalogued as rs935727455, COSV53720893; called by muse, mutect2, varscan2
- SLC12A6 | c.3048A>G p.Q1016= (on ENST00000354181 / NM_001365088.1; = p.Q965= on NM_005135.2) | Silent (SNP) | VAF 41/96 reads (43%) | catalogued as rs755892310, COSV51625989; called by muse, mutect2, varscan2
- SMG7 | c.2016C>T p.P672= | Silent (SNP) | VAF 116/294 reads (39%) | catalogued as COSV61630558; called by muse, mutect2, varscan2
- STC1 | c.303C>T p.N101= | Silent (SNP) | VAF 41/99 reads (41%) | catalogued as rs1027603215, COSV51688436; called by muse, mutect2, varscan2
- TRIML1 | c.255G>A p.V85= | Silent (SNP) | VAF 9/108 reads (8%) | catalogued as COSV60194261; called by muse, mutect2
- TTLL2 | c.1428G>C p.V476= | Silent (SNP) | VAF 43/140 reads (31%) | catalogued as rs768472898, COSV53443871; called by muse, mutect2, varscan2
- ZNF618 | c.1773C>T p.S591= (on ENST00000374126 / NM_001318042.2; = p.S498= on NM_133374.2) | Silent (SNP) | VAF 90/193 reads (47%) | catalogued as rs376102134; called by muse, mutect2, varscan2
- CDKL1 | c.742-1552T>C | Intron (SNP) | VAF 20/24 reads (83%) | catalogued as rs759951042, COSV53579576; called by muse, varscan2
- PDE4D | c.455+124913A>C | Intron (SNP) | VAF 19/300 reads (6%) | catalogued as COSV100504113; called by muse, mutect2
